Somatic mutation profile of tumor specimen TCGA-DU-A7TB-01A (aliquot TCGA-DU-A7TB-01A-11D-A33T-08) from TCGA case TCGA-DU-A7TB, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 56.7 years (20,704 days).
Specimen TCGA-DU-A7TB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9b6d856-12cc-4a0a-9d3b-e20c86ca6fb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A7TB-10A (Blood Derived Normal), aliquot TCGA-DU-A7TB-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3aec404a-1c6a-4221-a617-aeadea21843b

The open-access MAF lists 36 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 7, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM21 | c.161G>T p.S54I | Missense Mutation (SNP) | VAF 22/293 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV99961274; called by muse, mutect2
- AIFM3 | c.755G>A p.R252K | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100104898; called by muse, mutect2, varscan2
- ANK3 | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs967088925, COSV55045526, COSV99778108; called by muse, mutect2, varscan2
- ARID2 | c.1141C>A p.L381I | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV100535319; called by muse, mutect2, varscan2
- BLK | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1222621178, COSV52056291; called by muse, mutect2, varscan2
- CNOT3 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV99652185; called by muse, mutect2, varscan2
- DISP2 | c.3563G>A p.R1188Q | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs765406694, COSV99140286; called by muse, mutect2, varscan2
- EVC2 | c.321G>A p.M107I | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100186460; called by muse, mutect2, varscan2
- HIVEP1 | c.2578C>T p.P860S | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101045454; called by muse, mutect2, varscan2
- MROH2B | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101270836; called by muse, mutect2, varscan2
- NAF1 | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 19/105 reads (18%) | catalogued as rs1414961716, COSV99919286; called by muse, mutect2, varscan2
- PIK3R1 | c.1748_1750del p.X583_splice (on ENST00000521381 / NM_181523.3; = p.X313_splice on NM_181504.4) | Splice Site (DEL) | VAF 38/121 reads (31%) | catalogued as rs1131692243; called by pindel, varscan2
- PLEKHA8 | c.1341G>C p.W447C | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1562532320, COSV99321982; called by muse, mutect2, varscan2
- RHAG | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57704363; called by muse, mutect2, varscan2
- ROS1 | c.2597+1G>T p.X866_splice | Splice Site (SNP) | VAF 7/110 reads (6%) | catalogued as COSV100877494; called by muse, mutect2
- RRH | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.42); catalogued as rs372427391; called by muse, mutect2
- RSPO3 | c.313T>A p.C105S | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63151930; called by muse, mutect2, varscan2
- SCO2 | c.677T>C p.I226T | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs150742660; called by muse, mutect2, varscan2
- SH3BP5 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs1289820212, COSV53743114; called by muse, mutect2, varscan2
- SLC22A6 | c.1489G>T p.A497S | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.241); catalogued as COSV100842885, COSV64560953; called by muse, mutect2, varscan2
- TDP2 | c.995del p.R332Qfs*8 | Frame Shift Del (DEL) | VAF 51/161 reads (32%) | catalogued as COSV100593728; called by mutect2, pindel, varscan2
- TMEM203 | c.116G>C p.G39A | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV100411238; called by muse, mutect2, varscan2
- TNFRSF25 | c.1083C>G p.I361M | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as COSV100556899, COSV100557016, COSV61068630; called by muse, mutect2, varscan2
- TNXB | c.9626G>A p.G3209E (on ENST00000647633; = p.G2962E on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.248); catalogued as COSV100926474, COSV64475458; called by muse, mutect2
- TUT4 | c.4027C>T p.R1343* | Nonsense Mutation (SNP) | VAF 76/201 reads (38%) | catalogued as COSV99932614; called by muse, mutect2, varscan2
- VSIG2 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs148389397; called by muse, mutect2, varscan2
- ZMYM6 | c.1087A>G p.T363A | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100593275; called by muse, mutect2, varscan2
- CCDC146 | c.2156del p.Q719Rfs*14 | Frame Shift Del (DEL) | VAF 52/180 reads (29%) | called by mutect2, pindel, varscan2
- BACE2 | c.645C>T p.F215= | Silent (SNP) | VAF 74/218 reads (34%) | catalogued as rs779233833, COSV100161026; called by muse, mutect2, varscan2
- DTX3L | c.690A>G p.E230= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as rs1309494782, COSV99950098; called by muse, mutect2, varscan2
- FRY | c.45A>G p.K15= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV100969667; called by muse, mutect2, varscan2
- GLDN | c.765C>T p.S255= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV100117913; called by muse, mutect2, varscan2
- KNOP1 | c.1347C>T p.N449= | Silent (SNP) | VAF 149/445 reads (33%) | catalogued as rs377055424; called by muse, mutect2, varscan2
- SLC38A8 | c.1047G>A p.P349= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as rs556526539, COSV55306323; called by muse, mutect2, varscan2
- TTN | c.61857G>A p.E20619= (on ENST00000591111; = p.E13195= on NM_003319.4) | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV100622699; called by muse, mutect2, varscan2
- THRA | c.1110+102_1110+105del | Intron (DEL) | VAF 21/71 reads (30%) | called by mutect2, pindel, varscan2
